CCDI case PBCLLD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e1dc5fdd-cee8-4c4d-9864-53f15aca36f0

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,025 days).

Biospecimens (2 samples)
- Sample 0DUIWV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUIXS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
